CCDI case PBCMIJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/9f002c47-ef2c-4e00-8aa7-e3cc472e93ea

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.6 years (585 days).

Biospecimens (2 samples)
- Sample 0DVJNX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVJOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
